Somatic mutation profile of tumor specimen TCGA-E1-5322-01A (aliquot TCGA-E1-5322-01A-01D-1468-08) from TCGA case TCGA-E1-5322, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 38.1 years (13,903 days).
Specimen TCGA-E1-5322-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e21d7f9d-58a2-40de-b534-0888f181d863.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-5322-10A (Blood Derived Normal), aliquot TCGA-E1-5322-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ea04172-cf57-4ffd-ae71-fee5820e7a89

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Frame Shift Del 3, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 55/178 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 140/161 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABTB2 | c.2729C>T p.T910I | Missense Mutation (SNP) | VAF 106/241 reads (44%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.928); catalogued as COSV54393967; called by muse, mutect2, varscan2
- CTTN | c.437A>G p.E146G | Missense Mutation (SNP) | VAF 213/567 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV57235123; called by muse, mutect2, varscan2
- CWF19L2 | c.1250C>A p.T417K | Missense Mutation (SNP) | VAF 44/576 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV56518165; called by muse, mutect2
- DAW1 | c.78G>C p.K26N | Missense Mutation (SNP) | VAF 21/278 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV100006160, COSV59368027; called by muse, mutect2
- FLOT1 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 111/256 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs139987312; called by muse, varscan2
- FOXP4 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as COSV57222909; called by muse, mutect2, varscan2
- GLP2R | c.515A>T p.Y172F | Missense Mutation (SNP) | VAF 108/1036 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52328222; called by muse, mutect2, varscan2
- HRNR | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 46/474 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs537328568, COSV64260052; called by muse, mutect2, varscan2
- LAMA2 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 84/196 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367649718, COSV69000722; called by muse, mutect2, varscan2
- LIMCH1 | c.972-2A>C p.X324_splice | Splice Site (SNP) | VAF 10/19 reads (53%) | catalogued as COSV58292959; called by muse, varscan2
- MACC1 | c.1123T>C p.Y375H | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100256114, COSV60545507; called by muse, mutect2, varscan2
- MAP7D3 | c.489A>T p.R163S | Missense Mutation (SNP) | VAF 89/221 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60172087; called by muse, mutect2, varscan2
- OR2T1 | c.626del p.P209Lfs*4 | Frame Shift Del (DEL) | VAF 31/201 reads (15%) | catalogued as COSV100822237, COSV63541456; called by mutect2, pindel, varscan2
- SH2D3C | c.1366G>A p.A456T (on ENST00000314830 / NM_170600.3; = p.A299T on NM_005489.4) | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV59128300; called by muse, mutect2, varscan2
- TNRC6A | c.4786C>T p.R1596C | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs760467705, COSV59368699; called by muse, mutect2, varscan2
- ATRX | c.549del p.D184Ifs*22 | Frame Shift Del (DEL) | VAF 134/401 reads (33%) | called by mutect2, pindel, varscan2
- TASOR2 | c.2407_2408del p.N803Sfs*25 | Frame Shift Del (DEL) | VAF 64/296 reads (22%) | called by mutect2, pindel, varscan2
- NEK8 | c.1059C>T p.L353= | Silent (SNP) | VAF 43/101 reads (43%) | catalogued as COSV52047944, COSV99262340; called by muse, mutect2, varscan2
- OR5H6 | c.387T>C p.F129= (on ENST00000642105; = p.F113= on NM_001005479.2) | Silent (SNP) | VAF 33/400 reads (8%) | catalogued as COSV67351954; called by muse, mutect2
- RET | c.1779A>G p.G593= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV60704504; called by muse, mutect2, varscan2
- SESN2 | c.516C>T p.L172= | Silent (SNP) | VAF 64/162 reads (40%) | catalogued as rs373209094; called by muse, mutect2, varscan2
- C3P1 | n.3035G>A | RNA (SNP) | VAF 19/146 reads (13%) | called by muse, mutect2, varscan2
